Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7489, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7489-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right frontal lobe brain lesion.

Specimens Submitted:

1: Right frontal lobe brain lesion; biopsy

2: Right frontal lobe brain lesion #2; biopsy

DIAGNOSIS:

1. Right frontal lobe brain lesion; biopsy:

TUMOR TYPE:

Oligoastrocytoma

WHO GRADE:

II

MOLECULAR TESTING / IMMUNOHISTOCHEMISTRY:

EGFR FISH has been ordered and results will be issued in a separate report

1p/19q FISH has been ordered and results will be issued in a separate report

MGMT promoter methylation analysis has been ordered and results will be issued in a separate report and results will be issued in a separate report

Molecular testing for IDH mutations has been ordered and results will be reported separately

2. Right frontal lobe brain lesion #2; biopsy:

TUMOR TYPE:

Oligoastrocytoma

WHO GRADE:

II

Note: Immunohistochemical stains show that many tumor cells are positive for P53 (~60% of nuclear staining). MIB-1 immunostaining reveals a proliferation index of < 4%.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 and is qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	P53	
	NEG CONT	
	IMM RECUT	
	MIB-1 (Ki-67)	
	RECUT	

Gross Description:

1) The specimen is received fresh, labeled "Right frontal lobe brain lesion ". It consists of fragments measuring in aggregate 1 x 1 x 0.3 cm in aggregate. Touch prep made. Representative fragment for frozen. Rest submitted for permanent processing.

Summary of sections
FSC- frozen section control
U- undesignated

2. The specimen is received fresh, labeled "Right frontal lobe brain lesion number two" and consists of tan pink - white soft tissue measuring in aggregate 4 x 3.5 x 1.5. TPS is submitted and the remaining specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Right frontal lobe brain lesion; biopsy

Block	Sect. Site	PCs
1	fsc	1
1	U	1

Part 2: Right frontal lobe brain lesion #2; biopsy

Block	Sect. Site	PCs
5	U	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- Frozen section diagnosis: Right frontal lobe brain lesion Glioma; few mitoses seen in the smear
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 8d4d456f-cb98-4edd-b62f-a7285774183a (TCGA-HW-7489.E79AE11E-5076-4E1E-A077-C0488606AF9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).